CCDI case PBCEEB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/940722b7-9958-4b43-9ae4-c762d48c0ce4

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,724 days).

Biospecimens (3 samples)
- Sample 0DQB21: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQB2J: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQB2U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
